Somatic mutation profile of tumor specimen TCGA-55-6978-01A (aliquot TCGA-55-6978-01A-11D-1945-08) from TCGA case TCGA-55-6978, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-55-6978-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dc5f72c-383e-40a2-bb86-326477b4a0ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6978-11A (Solid Tissue Normal), aliquot TCGA-55-6978-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6c2020b-da2b-41bc-bfa8-74a299a9ddb2

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFB2 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV50064316; called by muse, mutect2, varscan2
- CEPT1 | c.1113T>G p.I371M | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV62959045, COSV62959863; called by muse, mutect2
- FCAMR | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs1344581313, COSV61367575; called by muse, mutect2
- GPR6 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763545349, COSV51571811; called by muse, mutect2, varscan2
- HCN4 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs528148663, COSV56083188; called by muse, mutect2, varscan2
- IL16 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs761611810, COSV57263047; called by muse, mutect2
- KCNB2 | c.1011G>C p.L337F | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73049977; called by muse, mutect2
- KCNH3 | c.2599C>T p.H867Y | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV57790577, COSV57792116; called by muse, mutect2, varscan2
- MTIF2 | c.600T>G p.F200L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55051328, COSV55052121; called by muse, mutect2
- NSF | c.1494T>G p.D498E | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56574718; called by muse, mutect2
- OR51A7 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63788276; called by muse, mutect2, varscan2
- PDILT | c.791A>G p.E264G | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV56701576; called by muse, mutect2
- PIGG | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV56317756; called by muse, mutect2, varscan2
- SACS | c.7421T>A p.I2474K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66539079; called by muse, mutect2, varscan2
- SEMA3E | c.257T>A p.I86N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV57088258; called by muse, mutect2, varscan2
- SETD5 | c.401G>C p.S134T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1408646715, COSV56710490; called by muse, mutect2, varscan2
- SLC25A34 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV53816843; called by muse, mutect2, varscan2
- SLIT3 | c.2831C>T p.P944L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV60606187; called by muse, mutect2, varscan2
- TBC1D9B | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.161); catalogued as COSV62281792; called by muse, mutect2
- UNC13A | c.2836A>G p.I946V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV53194374; called by muse, mutect2, varscan2
- ZFP57 | c.1166G>T p.C389F | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65306048; called by muse, mutect2, varscan2
- ZNF174 | c.113dup p.N38Kfs*6 | Frame Shift Ins (INS) | VAF 42/291 reads (14%) | catalogued as rs778043537; called by mutect2, varscan2
- A1CF | c.1316del p.L439* (on ENST00000373993 / NM_138932.2; = p.L431* on NM_014576.4) | Frame Shift Del (DEL) | VAF 17/121 reads (14%) | called by mutect2, pindel, varscan2
- FAT2 | c.1030del p.Y344Ifs*39 | Frame Shift Del (DEL) | VAF 18/202 reads (9%) | called by mutect2, pindel
- DSC3 | c.738A>C p.A246= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV64572761; called by muse, varscan2
- JADE2 | c.85A>C p.R29= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV50915397, COSV50918339; called by muse, mutect2, varscan2
- LZTR1 | c.309C>T p.C103= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV53147140; called by mutect2, varscan2
- PKDREJ | c.1068G>C p.L356= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV53548968; called by muse, mutect2, varscan2
- ZNF212 | c.63C>G p.S21= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV60025036; called by muse, mutect2
- AP000769.3 | chr11:65506110 A>G | 5'Flank (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
